FM case AD1580 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a01625b4-cbfd-4516-84d3-2838c13c73aa

Female, 47.2 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
